Somatic mutation profile of tumor specimen MP2PRT-PAVLUV-TMP1-A (aliquot MP2PRT-PAVLUV-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVLUV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,771 days).
Specimen MP2PRT-PAVLUV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fc441d4-2bab-4549-8491-08cdc05c95ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVLUV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVLUV-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18f25b77-1477-43da-ae7d-358915df5b36

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 21, Silent 5, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 36/169 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- BAHCC1 | c.6971C>T p.S2324L | Missense Mutation (SNP) | VAF 207/490 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868945099; called by muse, mutect2, varscan2
- CTCF | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 106/308 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750256116, COSV50466266; called by muse, mutect2, varscan2
- FAM155B | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV52936556; called by muse, mutect2, varscan2
- KCNS2 | c.1185C>G p.I395M | Missense Mutation (SNP) | VAF 87/266 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54640299; called by muse, mutect2, varscan2
- LIFR | c.976G>C p.V326L | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54698400; called by muse, mutect2, varscan2
- LTBP1 | c.1648G>A p.V550M (on ENST00000404816 / NM_206943.4; = p.V224M on NM_000627.4) | Missense Mutation (SNP) | VAF 102/310 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs767256539, COSV63185235; called by muse, mutect2, varscan2
- MYCBP2 | c.7912C>G p.L2638V (on ENST00000357337; = p.L2676V on NM_015057.5) | Missense Mutation (SNP) | VAF 95/228 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1266733033; called by muse, mutect2, varscan2
- NDUFA12 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 21/392 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100580855; called by muse, mutect2
- NPIPA7 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 73/152 reads (48%) | catalogued as COSV59820667; called by muse, mutect2, varscan2
- PRLHR | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 95/355 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1468621831, COSV99493049; called by muse, mutect2, varscan2
- YBX2 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 137/317 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs779812260; called by muse, mutect2
- BMPR1A | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- C10orf95 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 20/486 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- C8orf34 | c.1104G>T p.L368= | Splice Region (SNP) | VAF 8/189 reads (4%) | called by muse, mutect2
- CRACD | c.1988C>T p.S663F | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- FIZ1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MX2 | c.2122C>G p.Q708E | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PATJ | c.3467T>C p.V1156A | Missense Mutation (SNP) | VAF 95/213 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RFX7 | c.565G>A p.E189K (on ENST00000559447 / NM_001368074.1; = p.E286K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SATB2 | c.1892G>T p.S631I | Missense Mutation (SNP) | VAF 130/364 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SVEP1 | c.9492G>C p.Q3164H | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ZNF169 | c.1787A>T p.Q596L | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABLIM1 | c.1353G>A p.T451= | Silent (SNP) | VAF 121/353 reads (34%) | catalogued as rs758416758; called by muse, mutect2, varscan2
- DAAM2 | c.1641G>T p.L547= | Silent (SNP) | VAF 134/384 reads (35%) | catalogued as rs1221253107; called by mutect2, varscan2
- PLCE1 | c.2586G>T p.L862= | Silent (SNP) | VAF 170/462 reads (37%) | called by muse, mutect2, varscan2
- TMC7 | c.1509C>T p.F503= | Silent (SNP) | VAF 109/322 reads (34%) | catalogued as rs1304143562; called by muse, mutect2, varscan2
- TTN | c.37782G>T p.V12594= (on ENST00000591111; = p.V5170= on NM_003319.4) | Silent (SNP) | VAF 54/230 reads (23%) | catalogued as COSV60244399; called by muse, mutect2, varscan2
